Somatic mutation profile of tumor specimen TCGA-YL-A8SK-01B (aliquot TCGA-YL-A8SK-01B-21D-A377-08) from TCGA case TCGA-YL-A8SK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.8 years (24,759 days).
Specimen TCGA-YL-A8SK-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e1966ba-3a9f-4938-bc19-66678d87145b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SK-10A (Blood Derived Normal), aliquot TCGA-YL-A8SK-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c444668f-c30c-4f38-90a0-139368a26425

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 1, Splice Region 1, 5'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.4180G>A p.D1394N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99482949; called by muse, mutect2, varscan2
- ATN1 | c.2998C>G p.R1000G | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as rs782097731, COSV100755601; called by muse, mutect2, varscan2
- CCER1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62645835; called by muse, mutect2, varscan2
- DLG5 | c.4191C>T p.F1397= | Splice Region (SNP) | VAF 10/59 reads (17%) | catalogued as rs1372995130, COSV100967160; called by muse, mutect2, varscan2
- HPS5 | c.3297C>G p.C1099W (on ENST00000349215 / NM_181507.2; = p.C985W on NM_007216.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100752211, COSV61688194; called by muse, mutect2, varscan2
- LRRC8B | c.2324G>C p.R775P | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs369449390, COSV100446374, COSV100446415; called by muse, mutect2, varscan2
- MAP1A | c.3835A>G p.I1279V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100287822; called by muse, mutect2
- MORN4 | c.412T>A p.S138T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100167227; called by muse, mutect2
- PKNOX1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV99372560; called by muse, mutect2, varscan2
- PTPRH | c.3070G>A p.V1024M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766566365, COSV54747364; called by muse, mutect2, varscan2
- S100A8 | c.273C>A p.H91Q | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV100907086; called by muse, mutect2, varscan2
- SCMH1 | c.1505C>T p.S502F (on ENST00000326197 / NM_001031694.2; = p.S455F on NM_012236.4) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV58235021; called by muse, mutect2, varscan2
- SETX | c.6718A>C p.N2240H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99808443; called by muse, mutect2, varscan2
- SSX3 | c.486T>A p.H162Q | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100034880; called by muse, mutect2, varscan2
- SYNE1 | c.26009C>T p.S8670F (on ENST00000367255 / NM_182961.4; = p.S8622F on NM_033071.3) | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99548978; called by muse, mutect2, varscan2
- TP53BP1 | c.5531G>A p.R1844H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756730049, COSV99538594; called by muse, mutect2, varscan2
- TSC2 | c.2002G>T p.G668W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171806400, COSV99552126; called by muse, mutect2, varscan2
- TTI1 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs773992228, COSV100989546; called by muse, mutect2, varscan2
- UGGT1 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.445); catalogued as rs1241846310, COSV99390052; called by muse, mutect2, varscan2
- USP31 | c.996C>G p.H332Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV99564376; called by muse, mutect2
- ZMIZ1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV57902618; called by muse, mutect2, varscan2
- ZNF420 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100421072; called by muse, mutect2
- ZNF471 | c.1496G>T p.S499I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.238); catalogued as COSV100340273, COSV100340432; called by muse, mutect2, varscan2
- PROC | c.1199del p.G400Afs*21 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.2781A>G p.L927= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV101442872; called by muse, mutect2, varscan2
- DSG4 | c.2361G>A p.A787= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs761624597, COSV57398764; called by muse, mutect2, varscan2
- IGSF11 | c.1164C>T p.S388= (on ENST00000393775 / NM_001015887.3; = p.S387= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100676792; called by muse, mutect2, varscan2
- LILRB3 | c.1806C>A p.S602= (on ENST00000346401; = p.S590= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99556798; called by muse, mutect2, varscan2
- LRIT1 | c.924G>A p.T308= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs775567982, COSV100927965; called by muse, mutect2, varscan2
- PCDHGA12 | c.225C>T p.F75= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV52759561; called by muse, mutect2, varscan2
- PLEKHG4B | c.1506C>T p.S502= (on ENST00000283426; = p.S858= on NM_052909.5) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs373547646; called by muse, mutect2, varscan2
- ZNF407 | c.1449C>T p.C483= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99994508; called by muse, mutect2, varscan2
- ASF1B | c.-1G>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as rs756348906, COSV54617289, COSV99654188; called by muse, mutect2, varscan2
- MIR519A2 | n.29C>T | RNA (SNP) | VAF 29/162 reads (18%) | catalogued as rs142071806; called by muse, mutect2, varscan2
